Somatic mutation profile of tumor specimen TCGA-TM-A84B-01A (aliquot TCGA-TM-A84B-01A-11D-A36O-08) from TCGA case TCGA-TM-A84B, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 40.9 years (14,933 days).
Specimen TCGA-TM-A84B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f69d91f-d838-47cf-899b-deb45ca7b72a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84B-12A (Buccal Cell Normal), aliquot TCGA-TM-A84B-12A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39245949-8030-475d-9c49-e7d8971738c6

The open-access MAF lists 39 somatic variants for this specimen: 23 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 15, Splice Site 2, RNA 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.634+3_634+6del p.X212_splice | Splice Site (DEL) | VAF 47/64 reads (73%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ASB10 | c.547C>T p.R183C (on ENST00000420175 / NM_001142459.2; = p.R168C on NM_080871.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs151344605, CM121522, COSV99318828; ClinVar: not provided; called by muse, varscan2
- CD19 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs771929657, COSV100218226; called by muse, mutect2, varscan2
- CDH22 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV100952949; called by muse, mutect2, varscan2
- CDRT4 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 43/85 reads (51%) | catalogued as COSV100381588; called by muse, mutect2, varscan2
- CEACAM20 | c.1424G>C p.R475T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV100386970; called by muse, mutect2, varscan2
- HAO1 | c.254T>A p.M85K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101113276; called by muse, mutect2, varscan2
- HECW1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313775699, COSV101224123; called by muse, mutect2, varscan2
- HKDC1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs990696322, COSV100664706; called by muse, mutect2, varscan2
- IGKV2D-29 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101534391; called by muse, mutect2, varscan2
- JPT1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs868058942, COSV59173129; called by muse, mutect2
- MPDZ | c.6011G>T p.G2004V (on ENST00000319217 / NM_001330637.2; = p.G1975V on NM_003829.5) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351342832, COSV100057274; called by muse, mutect2, varscan2
- NDOR1 | c.1289-1G>A p.X430_splice (on ENST00000371521 / NM_001144026.3; = p.X423_splice on NM_014434.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100789073; called by muse, mutect2, varscan2
- PCDHA3 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs1554122491, COSV63539599; called by muse, mutect2, varscan2
- PXDN | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs755223854, COSV53234279; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SERPINB13 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs185543305, COSV99501188; called by muse, mutect2, varscan2
- SLC27A2 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs748482350, COSV51058317; called by muse, mutect2, varscan2
- SNED1 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1242479475, COSV100123155; called by muse, mutect2
- SRRM3 | c.704A>T p.E235V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100418824; called by muse, mutect2, varscan2
- TNFSF14 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.598); catalogued as rs769381794, COSV99838514; called by muse, mutect2, varscan2
- UNCX | c.454T>C p.W152R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285583587, COSV100310293; called by muse, mutect2, varscan2
- METTL24 | c.976_978del p.Q326del | In Frame Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- AHR | c.1977C>T p.F659= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as rs139422560; called by muse, mutect2, varscan2
- ATG4D | c.907C>T p.L303= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV100470314; called by muse, mutect2, varscan2
- BMS1 | c.1374C>T p.N458= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs372823965; called by muse, mutect2, varscan2
- C14orf39 | c.1536T>C p.N512= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV100407959; called by muse, mutect2, varscan2
- EDC4 | c.1923T>C p.A641= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100197729; called by muse, mutect2, varscan2
- ETAA1 | c.1929C>T p.S643= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as rs201848293, COSV55472381; called by muse, varscan2
- NLRP2 | c.1686C>T p.N562= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1259045887, COSV54758945; called by muse, mutect2, varscan2
- OBSCN | c.23145C>T p.R7715= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1410691196, COSV100804818; called by muse, mutect2, varscan2
- OR9G1 | c.198G>A p.S66= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs778129132, COSV56448890; called by muse, mutect2, varscan2
- PPFIA2 | c.1969T>C p.L657= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs573343081, COSV100334613; called by muse, mutect2, varscan2
- RAPSN | c.273C>T p.R91= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100100327; called by muse, mutect2, varscan2
- STAT1 | c.396C>T p.S132= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs1302624265, COSV100738780; called by muse, mutect2, varscan2
- TBCE | c.96G>C p.V32= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100783195; called by muse, mutect2, varscan2
- UGT2A1 | c.729G>A p.T243= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs141938191; called by muse, mutect2, varscan2
- WWP2 | c.2223C>T p.D741= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs757464706, COSV100598693; called by muse, mutect2, varscan2
- TUBB7P | n.612C>T | RNA (SNP) | VAF 8/26 reads (31%) | catalogued as rs782140532; called by mutect2, varscan2
